Gene-level copy-number profile of tumor specimen C3L-04037-03 (profiled together with C3L-04037-04) from CPTAC case C3L-04037, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.0 years (18,998 days).
Specimen C3L-04037-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f16bd46-13f1-4816-891b-56bef711857e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04037-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/79fb9ad1-3041-42fa-b707-0e00b66a965c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 22,153; copy number 2: 31,830; copy number 3: 3,902; copy number 4: 3; copy number 5: 665; copy number 6: 146; copy number 7: 191.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:69,306,469–69,358,177, 2 genes (within-gene range 0–1): AC114786.3, AC114786.2.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr19:1,228,287–1,238,027, 1 gene (within-gene range 0–1): CBARP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,002 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,461,221–144,305,180, 33 genes, copy number 6: AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1.
- chr5:50,396,192–51,383,332, 16 genes, copy number 6: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1.
- chr11:65,014,182–65,040,570, 1 gene, copy number 6 (within-gene range 2–6): ARL2-SNX15.
- chr11:65,025,390–104,682,581, 950 genes, copy number 5–7 (broad region; genes not listed).
- chr14:18,333,726–18,343,144, 2 genes, copy number 5: CR383658.1, RNU6-458P.

Autosomal genes at a single copy (total copy number 1): 19,322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
